Somatic mutation profile of tumor specimen TCGA-AX-A3FX-01A (aliquot TCGA-AX-A3FX-01A-11D-A228-09) from TCGA case TCGA-AX-A3FX, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 69.2 years (25,260 days).
Specimen TCGA-AX-A3FX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1600e5d9-c6e4-48b0-a6cb-b5be4432cb3a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AX-A3FX-10A (Blood Derived Normal), aliquot TCGA-AX-A3FX-10A-01D-A22A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f0f76ff2-89a9-4fc1-ae1b-65a8feb90f27

The open-access MAF lists 59 somatic variants for this specimen: 44 protein-altering or splice-affecting, 15 silent.
By variant classification: Missense Mutation 39, Silent 15, Nonsense Mutation 3, Translation Start Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1637A>C p.Q546P | Missense Mutation (SNP) | VAF 36/60 reads (60%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs397517201, COSV55875400, COSV55876869, COSV55877455; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.49C>T p.Q17* | Nonsense Mutation (SNP) | VAF 22/62 reads (35%) | catalogued as rs786204910, CM110130, CM1513152, COSV64288346; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAM21 | c.1920T>A p.N640K | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.175); catalogued as COSV99960709; called by muse, mutect2, varscan2
- ADGRF1 | c.86A>G p.K29R | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as rs1406660516, COSV100982570; called by muse, mutect2, varscan2
- ANKRA2 | c.323G>A p.G108E | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV99706975; called by muse, mutect2, varscan2
- ANKRD50 | c.2773C>G p.H925D | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV101538914; called by muse, mutect2, varscan2
- APOH | c.116C>G p.T39R | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV99235643; called by muse, mutect2
- ARHGAP15 | c.1322C>G p.A441G | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.148); catalogued as COSV54522369, COSV99709477; called by muse, mutect2
- BCORL1 | c.4406C>A p.T1469N | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.972); catalogued as rs1429249408, COSV99498864, COSV99498896; called by muse, mutect2, varscan2
- CEACAM3 | c.626C>T p.S209L | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs138403931; called by muse, mutect2, varscan2
- CELSR3 | c.2860G>T p.V954L | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV50840292, COSV99373022; called by muse, mutect2, varscan2
- CSMD3 | c.53A>G p.E18G | Missense Mutation (SNP) | VAF 15/201 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV99829178; called by muse, mutect2
- DCHS1 | c.9329A>G p.E3110G | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.053); catalogued as rs762887975, COSV100197284; called by muse, mutect2, varscan2
- DOCK11 | c.6024T>G p.D2008E | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.979); catalogued as COSV99353285; called by muse, mutect2, varscan2
- DOK1 | c.2T>G p.M1? | Translation Start Site (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV99283983; called by mutect2, varscan2
- EP300 | c.1040A>T p.H347L | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99607907; called by muse, mutect2, varscan2
- F12 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as COSV99499533; called by muse, mutect2, varscan2
- GPAT3 | c.425C>G p.T142S | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.368); catalogued as COSV100022867; called by muse, mutect2
- GRIK3 | c.1744G>A p.V582I | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.844); catalogued as rs371012951, COSV66136375, COSV66144296; called by muse, mutect2, varscan2
- GZMA | c.335A>T p.E112V | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.319); catalogued as COSV99956498; called by muse, mutect2, varscan2
- KLHL15 | c.1565G>A p.W522* | Nonsense Mutation (SNP) | VAF 21/52 reads (40%) | catalogued as COSV100044068; called by muse, mutect2, varscan2
- MAGEC1 | c.3424G>A p.E1142K | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.235); catalogued as COSV99595263; called by muse, mutect2, varscan2
- MDN1 | c.11182C>G p.Q3728E | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV101020973; called by muse, mutect2, varscan2
- MSH5 | c.1292G>A p.R431H | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs146419845; called by muse, mutect2, varscan2
- MUC5B | c.1055C>T p.A352V | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as rs748172935, COSV71595473; called by muse, mutect2, varscan2
- NNT | c.1898G>T p.G633V | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99238608; called by muse, mutect2, varscan2
- NOTCH4 | c.3037C>T p.Q1013* | Nonsense Mutation (SNP) | VAF 6/20 reads (30%) | catalogued as COSV100900523; called by muse, mutect2, varscan2
- PLEKHG2 | c.2927G>A p.G976D | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.169); catalogued as COSV99217072; called by muse, mutect2, varscan2
- PLXNB3 | c.5523G>T p.M1841I | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100737232; called by muse, mutect2, varscan2
- RPL18A | c.188A>G p.Y63C | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as rs1450160712, COSV55829756; called by muse, mutect2
- RSRP1 | c.755A>T p.N252I | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as COSV99682584; called by muse, mutect2, varscan2
- SLC44A5 | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as rs376030186; called by muse, mutect2, varscan2
- SOD1 | c.8C>T p.T3M | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV99532067; called by muse, mutect2, varscan2
- TBC1D16 | c.796G>C p.D266H | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.804); catalogued as COSV60477016, COSV60482027; called by muse, mutect2, varscan2
- TECPR1 | c.1063G>A p.A355T | Missense Mutation (SNP) | VAF 30/50 reads (60%) | SIFT tolerated (0.12); PolyPhen benign (0.125); catalogued as COSV101130324; called by muse, mutect2, varscan2
- TIMELESS | c.3152A>G p.N1051S | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.071); catalogued as COSV99973771; called by muse, mutect2, varscan2
- TOGARAM1 | c.1800G>T p.R600S | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV100753037; called by muse, mutect2, varscan2
- TRIM62 | c.1186C>G p.Q396E | Missense Mutation (SNP) | VAF 39/82 reads (48%) | SIFT tolerated (0.51); PolyPhen benign (0.253); catalogued as COSV99357712; called by muse, mutect2, varscan2
- VPS18 | c.1859G>A p.R620Q | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.153); catalogued as rs778448340, COSV99592384; called by muse, mutect2, varscan2
- VPS4B | c.560T>C p.V187A | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV99447810; called by muse, mutect2, varscan2
- ZNF527 | c.116A>C p.Y39S | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100648709; called by muse, mutect2, varscan2
- GAS2L2 | c.1405G>A p.G469S | Missense Mutation (SNP) | VAF 65/79 reads (82%) | SIFT tolerated (0.45); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PTEN | c.378_380del p.G127del | In Frame Del (DEL) | VAF 46/84 reads (55%) | called by mutect2, pindel, varscan2
- TRBV20-1 | c.310A>C p.S104R | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by mutect2, varscan2
- B3GLCT | c.75T>C p.F25= | Silent (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2, varscan2
- CEACAM20 | c.1731C>A p.I577= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV100386826; called by muse, varscan2
- CFAP46 | c.7632A>C p.S2544= | Silent (SNP) | VAF 3/37 reads (8%) | catalogued as COSV99584264, COSV99585336; called by muse, mutect2
- COL7A1 | c.5367C>T p.A1789= | Silent (SNP) | VAF 19/38 reads (50%) | catalogued as rs769323836, COSV100095481; called by muse, mutect2, varscan2
- DNAI4 | c.1764A>G p.V588= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as rs1206091581, COSV100925264; called by muse, mutect2, varscan2
- DUS4L | c.888G>A p.R296= | Silent (SNP) | VAF 30/75 reads (40%) | catalogued as COSV99143611; called by muse, mutect2, varscan2
- HJV | c.1176G>A p.E392= (on ENST00000336751 / NM_213653.4; = p.E279= on NM_145277.5) | Silent (SNP) | VAF 4/64 reads (6%) | catalogued as COSV100382234; called by muse, mutect2
- LHFPL3 | c.528C>T p.Y176= | Silent (SNP) | VAF 5/86 reads (6%) | catalogued as rs931116471, COSV101308303; called by muse, mutect2
- LRP2BP | c.537C>T p.L179= | Silent (SNP) | VAF 42/117 reads (36%) | catalogued as rs751514591, COSV100145916; called by muse, mutect2, varscan2
- MUC16 | c.9633C>G p.S3211= | Silent (SNP) | VAF 45/81 reads (56%) | catalogued as COSV101198976; called by muse, mutect2, varscan2
- NDUFAF1 | c.804G>C p.R268= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as COSV99531358; called by muse, mutect2
- PATJ | c.3015G>A p.V1005= | Silent (SNP) | VAF 22/57 reads (39%) | catalogued as COSV100333552, COSV57155096; called by muse, mutect2, varscan2
- PRG4 | c.1083C>T p.T361= | Silent (SNP) | VAF 13/89 reads (15%) | catalogued as COSV100823760; called by muse, mutect2, varscan2
- ROS1 | c.2547T>C p.V849= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as COSV100876726; called by muse, mutect2, varscan2
- SLC44A5 | c.1629C>A p.T543= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as COSV100901535; called by muse, mutect2, varscan2
